Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A73G, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A73G-01A (Primary Tumor).

ICD-O-3
Carcinoma, hepatocellular NOS
8770/3
Site Liver C22.0
9/28/13

TISSUE DESCRIPTION:

A1 A2 B1 B2 B3 B4 B5 C1

Tissue from segments II and III liver (1180.0 grams, 20.0 x 11.0 x 7.0 cm), tissue from segment VI liver (1.0 x 0.9 x 0.8 cm), and tissue from the left abdominal wall (biopsy, 2.6 x 2.2 x 1.0 cm).

DIAGNOSIS:

Liver, segments II and III, excision: Grade 3 (of 4) hepatocellular carcinoma forming a 20.0 x 11.0 x 7.0 cm mass. The surgical resection margin is negative for tumor by at least 0.2 cm.

Liver, segment VI, excision: Hyalinized nodule consistent with old sclerosed hemangioma.

Soft tissue, left abdominal wall, biopsy: Fibrin, inflammation, and reactive mesothelial cells. Negative for tumor. (Seen with Dr.

Source: NCI Genomic Data Commons file abbf3b33-9ac4-4478-8509-b4b0c668d0d8 (TCGA-DD-A73G.C7A70BE1-34F6-4500-8C6C-A0D4FBBBD251.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).